Somatic mutation profile of tumor specimen MMRF_2624_1_BM_CD138pos (aliquot MMRF_2624_1_BM_CD138pos_T1_KHS5U_L13296) from MMRF case MMRF_2624, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.3 years (21,282 days).
Specimen MMRF_2624_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8d3c8b2-8b63-4be6-9321-bf1f74fc88a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2624_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2624_1_PB_WBC_C2_KHS5U_L13297; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b3ccb94-b752-4a70-b593-85bbc6cd8306

The open-access MAF lists 99 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 29, Silent 12, Intron 8, 5'UTR 5, 3'Flank 3, Frame Shift Del 2, 5'Flank 1, Splice Region 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1902T>A p.D634E (on ENST00000288602 / NM_001374244.1; = p.D594E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs121913337, COSV56082626, COSV56195504, COSV56284149; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL2 | c.3271G>A p.A1091T | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749408482, COSV55459015; called by muse, mutect2, varscan2
- AVPI1 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101033343; called by muse, mutect2, varscan2
- CADPS2 | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1289591025; called by muse, mutect2, varscan2
- CASKIN2 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs780367601; called by muse, mutect2, varscan2
- CFAP52 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759409222, COSV55342735; called by muse, mutect2, varscan2
- DYSF | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs773773555, COSV50285446; called by muse, mutect2, varscan2
- EIF2AK4 | c.1331A>G p.Y444C | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1203740787; called by muse, mutect2, varscan2
- FAR2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1211073289; called by muse, mutect2, varscan2
- FER1L5 | c.2989C>T p.R997C (on ENST00000623019; = p.R1004C on NM_001293083.2) | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1268232963; called by muse, mutect2, varscan2
- IGHJ5 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | PolyPhen benign (0.003); catalogued as rs782494105; called by muse, varscan2
- KLB | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 105/250 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs369568090, COSV57300324; called by muse, mutect2, varscan2
- KLHL25 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.516); catalogued as rs777051060; called by muse, mutect2, varscan2
- KMT2D | c.7129C>T p.P2377S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs750933281; ClinVar: likely benign; called by muse, mutect2, varscan2
- MVP | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as rs1444677208; called by muse, mutect2, varscan2
- NKX2-8 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1456813425, COSV51874295; called by muse, mutect2, varscan2
- NRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752508313, COSV54744579, COSV54745979; called by muse, mutect2, varscan2
- OPLAH | c.2957C>T p.S986L | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1332726078; called by muse, mutect2, varscan2
- OR4F15 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as rs1228466075, COSV59969062, COSV99046067; called by muse, mutect2, varscan2
- PSMD1 | c.566A>G p.Q189R | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs749581365; called by mutect2, varscan2
- RELA | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV58014786; called by muse, mutect2, varscan2
- TULP4 | c.4178C>T p.S1393L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV104424662; called by muse, mutect2, varscan2
- ZNF665 | c.1469C>T p.S490L (on ENST00000600412; = p.S555L on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs766646492, COSV67214215; called by muse, mutect2, varscan2
- ACSM2B | c.1410G>A p.G470= | Splice Region (SNP) | VAF 45/260 reads (17%) | called by muse, mutect2, varscan2
- CCNE1 | c.1135A>G p.M379V | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCHO1 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HUWE1 | c.2169_2186del p.E723_E728del | In Frame Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, pindel, varscan2
- ITGAE | c.2758C>A p.H920N | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNA5 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MDGA2 | c.2097del p.Y700Mfs*30 (on ENST00000399232 / NM_001113498.2; = p.Y402Mfs*30 on NM_182830.4) | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- MTMR1 | c.328+2T>C p.X110_splice | Splice Site (SNP) | VAF 74/107 reads (69%) | called by muse, mutect2, varscan2
- MYH11 | c.1954A>G p.T652A | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PABPC4 | c.828A>T p.L276F | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PPP4R3C | c.1774A>G p.N592D | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SF3B2 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TTC26 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- UPK3B | c.427A>T p.T143S (on ENST00000257632; = p.T88S on NM_001347684.2) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZBTB7C | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ZFHX3 | c.9824del p.P3275Rfs*9 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | called by mutect2, pindel, varscan2
- ZNF540 | c.1654G>C p.D552H | Missense Mutation (SNP) | VAF 128/261 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ZNF548 | c.71A>C p.H24P | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ADAMTS8 | c.1503C>T p.C501= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as rs747352814; called by muse, mutect2, varscan2
- CHST12 | c.789C>T p.N263= | Silent (SNP) | VAF 90/246 reads (37%) | catalogued as rs754781266; called by muse, mutect2, varscan2
- COL6A3 | c.9240G>A p.Q3080= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.1329C>T p.I443= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs770746234; called by mutect2, varscan2
- DPP7 | c.303A>G p.L101= | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- FSCN2 | c.339C>T p.G113= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- IMPA1 | c.618C>T p.G206= | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as rs200215384; called by muse, mutect2, varscan2
- KCNQ1 | c.1920G>A p.Q640= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as rs1266823987; called by muse, mutect2, varscan2
- MAGEB5 | c.159C>T p.Y53= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs774664080; called by muse, mutect2, varscan2
- MUC22 | c.2793A>C p.T931= | Silent (SNP) | VAF 197/547 reads (36%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.528A>T p.I176= | Silent (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- TRPM7 | c.1743T>A p.I581= | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.*2734A>G | 3'UTR (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.*251G>A | 3'UTR (SNP) | VAF 35/125 reads (28%) | called by muse, mutect2, varscan2
- AKT2 | c.*1326T>C | 3'UTR (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- ALDOB | c.*329T>C | 3'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- AR | c.1885+8869G>T | Intron (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>A | 5'Flank (SNP) | VAF 51/126 reads (40%) | catalogued as COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- CAPS2 | c.1670-1574T>G | Intron (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- CDCP1 | c.*2142G>A | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- DDX3X | c.*617G>A | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- FAM102A | c.-262C>T | 5'UTR (SNP) | VAF 77/114 reads (68%) | called by muse, mutect2, varscan2
- FGF14 | c.408+128G>A | Intron (SNP) | VAF 10/43 reads (23%) | catalogued as rs548959237, COSV65948499; called by muse, mutect2, varscan2
- FUT9 | c.*100T>A | 3'UTR (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- GAB1 | chr4:143470859 ins T | 3'Flank (INS) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- GABRA4 | c.*5691T>G | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- GPR176 | c.*956T>C | 3'UTR (SNP) | VAF 81/153 reads (53%) | called by muse, mutect2, varscan2
- HOGA1 | c.*979C>T | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- HSPA12A | c.*121A>C | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- IDI1 | c.*537del | 3'UTR (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- IFI44L | c.*963A>G | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- INPP4B | chr4:142027353 C>A | 3'Flank (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- INTS8 | c.*727C>G | 3'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- ITGB4 | c.2782+39C>T | Intron (SNP) | VAF 52/222 reads (23%) | called by muse, mutect2, varscan2
- LAD1 | c.*167A>C | 3'UTR (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- LIMD2 | c.-24C>T | 5'UTR (SNP) | VAF 13/57 reads (23%) | catalogued as COSV51991831; called by muse, mutect2, varscan2
- LRRIQ1 | c.5016+192T>A | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- MGAT4D | c.*1070T>G | 3'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- MSANTD1 | c.*193C>A | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- MYO1E | c.-112C>G | 5'UTR (SNP) | VAF 66/116 reads (57%) | called by muse, varscan2
- MYO1E | c.-116G>C | 5'UTR (SNP) | VAF 22/112 reads (20%) | called by muse, varscan2
- MYO1E | c.-177A>G | 5'UTR (SNP) | VAF 16/97 reads (16%) | catalogued as rs1398474853; called by muse, varscan2
- ONECUT2 | c.*4678C>A | 3'UTR (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- ORAI2 | c.*3590T>C | 3'UTR (SNP) | VAF 68/149 reads (46%) | called by muse, varscan2
- ORAI2 | c.*3643T>A | 3'UTR (SNP) | VAF 70/136 reads (51%) | called by muse, varscan2
- ORC1 | c.*266C>T | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- PHF20L1 | c.1579+951T>C | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as rs1240879876; called by muse, mutect2, varscan2
- PLA1A | c.*304A>G | 3'UTR (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- RNF146 | c.*657A>C | 3'UTR (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- ROBO2 | c.1683-415A>C | Intron (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*499C>A | 3'UTR (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- SBK1 | c.*299C>T | 3'UTR (SNP) | VAF 7/56 reads (13%) | catalogued as rs1473131759; called by muse, varscan2
- SCUBE2 | c.2854+60G>A | Intron (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- SHANK2 | c.*2632A>C | 3'UTR (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- SSTR1 | c.*1293T>C | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- STAT2 | c.*139C>G | 3'UTR (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- TAOK2 | chr16:29991230 G>A | 3'Flank (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- ZNF12 | c.*393A>G | 3'UTR (SNP) | VAF 52/114 reads (46%) | catalogued as rs1427368435; called by mutect2, varscan2
